Somatic mutation profile of tumor specimen TCGA-60-2708-01A (aliquot TCGA-60-2708-01A-01W-0877-08) from TCGA case TCGA-60-2708, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.9 years (23,691 days).
Specimen TCGA-60-2708-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fffc8b0-7c7c-4fa6-a95d-a67eb04a1dbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2708-11A (Solid Tissue Normal), aliquot TCGA-60-2708-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c59521a-e6f3-4e0a-b185-0b4134499bcf

The open-access MAF lists 191 somatic variants for this specimen: 141 protein-altering or splice-affecting, 47 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 47, Frame Shift Del 10, Nonsense Mutation 10, Frame Shift Ins 2, In Frame Del 2, 5'Flank 1, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7784T>C p.L2595P | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV71289347; called by muse, mutect2, varscan2
- ABCD4 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1204078851, COSV53992851, COSV53995075; called by muse, mutect2
- ADAM21 | c.1186A>T p.N396Y | Missense Mutation (SNP) | VAF 220/323 reads (68%) | SIFT tolerated (0.89); PolyPhen benign (0.05); catalogued as COSV50796291; called by muse, mutect2, varscan2
- ADAMTS20 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 44/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67132970, COSV67140910; called by muse, mutect2, varscan2
- ADGRG4 | c.526C>A p.R176S | Missense Mutation (SNP) | VAF 222/556 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV54951846, COSV54957798; called by muse, mutect2, varscan2
- AFF4 | c.2039C>A p.S680* | Nonsense Mutation (SNP) | VAF 41/92 reads (45%) | catalogued as COSV54795579; called by muse, mutect2, varscan2
- AOX1 | c.2921T>A p.I974N | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV65982056; called by muse, mutect2, varscan2
- APPBP2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs140223877; called by muse, mutect2, varscan2
- ARMCX2 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV57530317, COSV57531528; called by muse, mutect2, varscan2
- ASNSD1 | c.326del p.L109Cfs*107 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | catalogued as rs763026988; called by mutect2, pindel, varscan2
- BRINP3 | c.1879A>T p.I627F | Missense Mutation (SNP) | VAF 122/779 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.326); catalogued as COSV66526989; called by muse, mutect2, varscan2
- CACNA1A | c.4922T>G p.V1641G | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64200153; called by muse, mutect2, varscan2
- CACNG2 | c.932T>A p.L311H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV55635821; called by muse, varscan2
- CASS4 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV64386769; called by muse, mutect2, varscan2
- CCNJL | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV57445187; called by muse, mutect2, varscan2
- CDX4 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as COSV65171698; called by muse, mutect2, varscan2
- CENPF | c.8218A>T p.S2740C | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV65275581; called by muse, mutect2, varscan2
- CENPT | c.201G>T p.R67S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV54650236; called by muse, mutect2, varscan2
- CHMP3 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55686404, COSV99806491; called by muse, mutect2, varscan2
- CNGB3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 81/347 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs146488853, COSV99082035; called by muse, mutect2, varscan2
- CNTN4 | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.264); catalogued as COSV61874368; called by muse, mutect2, varscan2
- CRCP | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | catalogued as COSV58535870; called by muse, mutect2, varscan2
- CRYBG3 | c.8626C>G p.Q2876E | Missense Mutation (SNP) | VAF 67/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51712540; called by muse, mutect2, varscan2
- CSMD3 | c.2218G>T p.G740W (on ENST00000297405 / NM_001363185.1; = p.G636W on NM_052900.3) | Missense Mutation (SNP) | VAF 115/451 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52217569; called by muse, mutect2, varscan2
- CSRNP1 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as rs1427983004, COSV56187097, COSV56188330; called by muse, mutect2, varscan2
- CYLC1 | c.1203G>C p.K401N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61412724; called by muse, mutect2, varscan2
- DAB1 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100139985, COSV59729336; called by muse, mutect2, varscan2
- DCSTAMP | c.373A>T p.M125L | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs760646948, COSV52578096; called by muse, mutect2, varscan2
- DENND3 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52803026; called by muse, mutect2
- DNAJC14 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 125/387 reads (32%) | catalogued as COSV57913181; called by muse, mutect2, varscan2
- EFL1 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV51606331; called by muse, mutect2, varscan2
- ENPP3 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as COSV62954575; called by muse, mutect2, varscan2
- EPB41L2 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 28/430 reads (7%) | catalogued as COSV61356176; called by muse, mutect2
- FAIM2 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739707; called by muse, mutect2, varscan2
- FAM102A | c.494C>T p.P165L (on ENST00000373095 / NM_001035254.3; = p.P23L on NM_203305.2) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.212); catalogued as COSV55947712; called by muse, mutect2, varscan2
- FAM107B | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV51686090; called by muse, mutect2, varscan2
- FAM47A | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV60497417; called by muse, mutect2, varscan2
- FHL5 | c.340C>G p.R114G | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58738007; called by muse, mutect2
- FLRT2 | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 101/134 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs988486068, COSV58143368; called by muse, mutect2, varscan2
- FNIP1 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 100/162 reads (62%) | catalogued as COSV57197045; called by muse, mutect2, varscan2
- FRMD3 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV58462914; called by muse, mutect2, varscan2
- GOLGA3 | c.4241T>A p.L1414Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52633541; called by mutect2, varscan2
- GRIA4 | c.1370A>G p.H457R | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV56900349; called by muse, mutect2, varscan2
- HCK | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1299403458, COSV52943396; called by muse, mutect2, varscan2
- HECW1 | c.3728T>A p.F1243Y | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67831313; called by muse, mutect2, varscan2
- HNRNPH2 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 99/647 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.059); catalogued as COSV57266273; called by muse, mutect2, varscan2
- HOXC11 | c.264C>G p.S88R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV54533356; called by muse, mutect2, varscan2
- HRNR | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV100912733, COSV64259033; called by muse, mutect2, varscan2
- HSPA6 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59060757; called by muse, varscan2
- HSPA6 | c.1735G>T p.V579F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV59061489; called by muse, mutect2
- HTR2A | c.720T>A p.F240L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.071); catalogued as COSV66327488; called by muse, mutect2, varscan2
- IGBP1 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60556513; called by muse, mutect2, varscan2
- ITPKB | c.2322C>G p.I774M | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV55263096, COSV99684488, COSV99685002; called by muse, mutect2, varscan2
- JADE3 | c.783A>T p.K261N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54467105; called by muse, mutect2, varscan2
- KALRN | c.5346G>T p.K1782N (on ENST00000360013 / NM_001024660.4; = p.K85N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as COSV52258178; called by muse, mutect2, varscan2
- KIF15 | c.3451C>A p.H1151N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58161457; called by muse, mutect2, varscan2
- KRT37 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as COSV56658352; called by muse, mutect2, varscan2
- KRT6A | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58105598; called by muse, mutect2, varscan2
- LAMB1 | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV55965878; called by muse, mutect2, varscan2
- LRCH4 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs769644731, COSV53826630; called by mutect2, varscan2
- LRRC42 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.219); catalogued as COSV59961031, COSV59961486; called by muse, mutect2, varscan2
- LRRC7 | c.406G>C p.D136H (on ENST00000651989 / NM_001370785.2; = p.D103H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV104377469, COSV50473346; called by muse, mutect2, varscan2
- LRRIQ3 | c.146G>T p.C49F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV63044831; called by muse, mutect2, varscan2
- MAGEB6B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs752201353, COSV69689719; called by muse, mutect2, varscan2
- MAN1A2 | c.180_184del p.S61Tfs*5 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV62979181; called by mutect2, pindel, varscan2
- MAPK13 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52983363; called by muse, mutect2
- MED12 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV100375970; called by muse, mutect2, varscan2
- MTPN | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as rs1259441024, COSV67599742; called by muse, mutect2, varscan2
- MYO18A | c.3090C>T p.D1030= | Splice Region (SNP) | VAF 17/31 reads (55%) | catalogued as rs752966597, COSV62862118; called by muse, mutect2, varscan2
- NEU1 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57667561; called by muse, mutect2, varscan2
- NF1 | c.8466G>C p.Q2822H (on ENST00000358273 / NM_001042492.3; = p.Q2801H on NM_000267.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62206245; called by mutect2, varscan2
- NLRP8 | c.967A>C p.T323P | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as COSV52588732, COSV99405333; called by muse, mutect2, varscan2
- NRK | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54598385; called by muse, mutect2, varscan2
- NUCKS1 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV65652994; called by muse, mutect2, varscan2
- OPHN1 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62782904; called by muse, mutect2
- OR10G8 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV70908649; called by muse, mutect2, varscan2
- OR11H12 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 263/403 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV73543668; called by muse, mutect2, varscan2
- OR2F1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67331513; called by muse, mutect2, varscan2
- OR2G3 | c.755A>T p.Y252F | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.469); catalogued as COSV60681959; called by muse, mutect2, varscan2
- OR2T1 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV63542126; called by muse, mutect2, varscan2
- OR4D11 | c.584T>A p.L195H | Missense Mutation (SNP) | VAF 97/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57585852; called by muse, mutect2
- OR51I1 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374695087, COSV66508167; called by muse, mutect2, varscan2
- OR5M11 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 96/321 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV73141846; called by muse, mutect2, varscan2
- OR8H1 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57294375; called by muse, mutect2, varscan2
- PARN | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV58366977; called by muse, mutect2
- PCDH11X | c.3032C>A p.P1011Q | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs758409007, COSV53446504; called by muse, mutect2, varscan2
- PCDH19 | c.2904C>A p.D968E (on ENST00000373034 / NM_001184880.2; = p.D920E on NM_020766.3) | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55264658; called by muse, mutect2, varscan2
- PCDHGB2 | c.820A>C p.N274H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV53963391; called by muse, mutect2, varscan2
- PEAK1 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56930084, COSV56936742; called by muse, mutect2, varscan2
- PEX5L | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as COSV55847502; called by muse, mutect2, varscan2
- PHKA1 | c.1201A>T p.M401L | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as COSV59806900; called by muse, mutect2, varscan2
- PIK3C2B | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV65803728; called by muse, mutect2, varscan2
- PLEKHA8 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV51651685; called by muse, mutect2, varscan2
- PPP1R26 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs1274929918, COSV63355856; called by muse, mutect2, varscan2
- PRPF4B | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61784409; called by muse, mutect2, varscan2
- PTPN13 | c.334dup p.A112Gfs*2 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs762510393; called by pindel, varscan2
- RFX3 | c.2153C>G p.P718R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); catalogued as COSV65861313; called by muse, mutect2, varscan2
- RXFP1 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV57051118; called by muse, mutect2, varscan2
- RYR2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200685968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL2 | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as rs946358719, COSV58103776; called by muse, mutect2, varscan2
- SETX | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 96/190 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56387201; called by muse, mutect2, varscan2
- SHF | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 51/88 reads (58%) | catalogued as COSV52049442, COSV52050825; called by muse, mutect2, varscan2
- SIPA1L1 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62170802; called by muse, mutect2
- SKAP1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); catalogued as COSV61147380, COSV61152106; called by muse, mutect2, varscan2
- SLC17A2 | c.726T>A p.S242R | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as COSV55352572; called by muse, mutect2, varscan2
- SMARCA2 | c.2301G>A p.M767I | Missense Mutation (SNP) | VAF 149/269 reads (55%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.954); catalogued as COSV61808573; called by muse, mutect2, varscan2
- SMOC2 | c.1192G>A p.V398M (on ENST00000356284 / NM_001166412.2; = p.V409M on NM_022138.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs754482354, COSV62439085; called by muse, mutect2, varscan2
- SPATA2 | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV56866869; called by muse, mutect2, varscan2
- STAT1 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as COSV63116443, COSV63117578; called by muse, mutect2, varscan2
- STK39 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63598070; called by muse, mutect2, varscan2
- SYNGAP1 | c.1873C>T p.L625F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53382144, COSV99537858; called by muse, mutect2
- SYT10 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 47/164 reads (29%) | catalogued as COSV57341346, COSV99951367; called by muse, mutect2, varscan2
- TAB3 | c.701A>G p.Q234R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.306); catalogued as COSV55837638; called by muse, mutect2, varscan2
- TECRL | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 152/300 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1055028800, COSV67087591; called by muse, mutect2, varscan2
- TFDP3 | c.372G>T p.R124S | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV59537160; called by muse, mutect2, varscan2
- TLE1 | c.1852G>C p.G618R | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64719361, COSV64719460, COSV64723155; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TRIM42 | c.1753C>A p.Q585K | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as rs778325086, COSV53883675; called by muse, mutect2, varscan2
- TRIM58 | c.1218A>C p.E406D | Missense Mutation (SNP) | VAF 145/829 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.091); catalogued as COSV63570669; called by muse, mutect2, varscan2
- USP29 | c.1857G>C p.Q619H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.362); catalogued as COSV54143502; called by mutect2, varscan2
- UTP14A | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV64087056; called by muse, mutect2, varscan2
- VPS41 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs377296574; called by muse, mutect2, varscan2
- VSIG4 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775339601, COSV66073482; called by muse, mutect2, varscan2
- ZFHX4 | c.1020A>T p.K340N | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.691); catalogued as COSV50682756, COSV50970085, COSV51469134; called by muse, mutect2, varscan2
- ZFP42 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV58817768; called by muse, mutect2, varscan2
- ZNF41 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57443214; called by muse, mutect2, varscan2
- ATP1A2 | c.327_336del p.F110Tfs*57 | Frame Shift Del (DEL) | VAF 46/309 reads (15%) | called by mutect2, pindel, varscan2
- CNOT4 | c.1772_1774del p.N591del (on ENST00000541284 / NM_001190850.1; = p.N588del on NM_001190849.2) | In Frame Del (DEL) | VAF 112/360 reads (31%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2216A>T p.H739L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.73); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DYNC2H1 | c.3498G>T p.W1166C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2AK1 | c.1230del p.C411Vfs*17 | Frame Shift Del (DEL) | VAF 18/201 reads (9%) | called by mutect2, varscan2
- H2BC9 | c.155_160del p.D52_T53del | In Frame Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- HADHA | c.1706A>G p.K569R | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.049); called by muse, mutect2
- LRRCC1 | c.1214dup p.P406Afs*4 | Frame Shift Ins (INS) | VAF 20/120 reads (17%) | called by pindel, varscan2
- LRRCC1 | c.1215_1216del p.K405Nfs*4 | Frame Shift Del (DEL) | VAF 40/118 reads (34%) | called by muse*, mutect2, varscan2*
- NDUFS1 | c.211_236del p.V71Cfs*2 | Frame Shift Del (DEL) | VAF 24/134 reads (18%) | called by mutect2, pindel
- PICALM | c.569del p.N190Mfs*3 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | called by mutect2, pindel, varscan2
- TMEM236 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 36/1196 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- TTN | c.102212_102218del p.N34071Mfs*37 (on ENST00000591111; = p.N26647Mfs*37 on NM_003319.4) | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- VN1R5 | c.458T>A p.L153* | Nonsense Mutation (SNP) | VAF 73/330 reads (22%) | called by muse, mutect2, varscan2
- ZNF43 | c.516del p.K172Nfs*18 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- ADAM22 | c.1992A>G p.L664= | Silent (SNP) | VAF 66/216 reads (31%) | catalogued as COSV55969422, COSV55978930; called by muse, mutect2, varscan2
- ADCY1 | c.1485G>T p.P495= | Silent (SNP) | VAF 57/173 reads (33%) | catalogued as COSV52035834; called by muse, mutect2, varscan2
- ADCY8 | c.501A>G p.E167= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV53911286; called by muse, mutect2
- AJUBA | c.1395C>T p.A465= | Silent (SNP) | VAF 70/86 reads (81%) | catalogued as COSV52985482, COSV99400827; called by muse, mutect2, varscan2
- ARFGEF3 | c.231G>A p.S77= | Silent (SNP) | VAF 53/256 reads (21%) | catalogued as rs138636575; called by muse, mutect2, varscan2
- ARID1B | c.4368T>C p.N1456= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs769362465, COSV51665019; called by muse, mutect2, varscan2
- ATP7B | c.2979G>A p.T993= | Silent (SNP) | VAF 4/6 reads (67%) | catalogued as rs200656411, COSV54439477; called by mutect2, varscan2
- BCAN | c.834G>A p.Q278= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV61257287; called by muse, mutect2, varscan2
- CACNA1S | c.3201C>G p.T1067= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV62940425; called by muse, mutect2, varscan2
- CARD10 | c.2280G>T p.R760= | Silent (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- CLCN4 | c.1089C>A p.T363= | Silent (SNP) | VAF 54/268 reads (20%) | catalogued as COSV66466869; called by muse, mutect2, varscan2
- COX10 | c.336G>A p.K112= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV55405569; called by muse, mutect2, varscan2
- CYP2A13 | c.27G>A p.V9= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV57838290; called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- DUSP11 | c.813C>T p.L271= | Silent (SNP) | VAF 79/415 reads (19%) | catalogued as rs761885998, COSV55593987; called by muse, mutect2, varscan2
- DYNC2LI1 | c.966C>T p.V322= | Silent (SNP) | VAF 84/227 reads (37%) | catalogued as rs752987596, COSV53183763; called by muse, mutect2, varscan2
- EIF4G2 | c.579C>T p.L193= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1258630610, COSV60597412; called by muse, mutect2, varscan2
- EP400 | c.4710A>T p.I1570= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV57774908; called by muse, mutect2, varscan2
- EPG5 | c.1374C>G p.L458= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV56350936; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1821A>G p.P607= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs769929150, COSV51618958; called by muse, mutect2, varscan2
- ETAA1 | c.552A>T p.T184= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV55473376; called by muse, mutect2
- EXPH5 | c.459A>C p.A153= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as COSV56203353; called by muse, mutect2, varscan2
- GLA | c.630C>A p.P210= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV54509664; called by muse, mutect2
- H2BC7 | c.354C>A p.A118= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs773729867, COSV61912028; called by muse, mutect2, varscan2
- HOXC12 | c.654C>T p.R218= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV54535119; called by muse, mutect2, varscan2
- IGKV2D-28 | c.351A>T p.L117= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV101494561, COSV101494564; called by mutect2, varscan2
- ITPR2 | c.4908A>G p.E1636= | Silent (SNP) | VAF 122/396 reads (31%) | catalogued as rs1488842987, COSV67270468; called by muse, mutect2, varscan2
- MAGEA3 | c.387G>A p.P129= | Silent (SNP) | VAF 76/162 reads (47%) | catalogued as rs144510184, COSV64756262; called by muse, mutect2, varscan2
- MAN2B1 | c.504C>T p.I168= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs769374044; called by muse, varscan2
- NCAN | c.3063G>C p.G1021= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV53052369; called by muse, mutect2, varscan2
- NLGN3 | c.2151C>T p.S717= (on ENST00000358741 / NM_181303.2; = p.S697= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV62443609; called by muse, mutect2, varscan2
- OR10S1 | c.748C>A p.R250= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV73342827; called by muse, mutect2, varscan2
- OR51I2 | c.148C>A p.R50= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs145725236, COSV58298994; called by muse, mutect2, varscan2
- OR5W2 | c.231T>A p.T77= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV60616484; called by muse, mutect2, varscan2
- PLCL1 | c.2286G>A p.S762= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs144546582; called by muse, mutect2, varscan2
- PTER | c.327G>T p.T109= | Silent (SNP) | VAF 53/92 reads (58%) | catalogued as rs147446984, COSV54346040; called by muse, mutect2, varscan2
- RBAK | c.1941A>G p.G647= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV62331619; called by muse, mutect2
- RBBP9 | c.411C>T p.D137= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as rs565219087, COSV61499970; called by muse, mutect2, varscan2
- SHPRH | c.3480G>A p.Q1160= (on ENST00000275233 / NM_001042683.3; = p.Q1169= on NM_173082.3) | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as rs1247830255, COSV51611385; called by muse, mutect2, varscan2
- SPOPL | c.1155A>T p.P385= | Silent (SNP) | VAF 806/1820 reads (44%) | catalogued as COSV54513932; called by muse, mutect2, varscan2
- TMC2 | c.1107C>T p.G369= | Silent (SNP) | VAF 92/285 reads (32%) | catalogued as rs749847002, COSV62653726; called by muse, mutect2, varscan2
- TTN | c.97305G>A p.K32435= (on ENST00000591111; = p.K25011= on NM_003319.4) | Silent (SNP) | VAF 42/185 reads (23%) | catalogued as COSV60112712; called by muse, mutect2, varscan2
- VANGL2 | c.687G>A p.V229= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV63604638; called by muse, mutect2, varscan2
- ZC4H2 | c.450C>A p.P150= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1388052176, COSV62004363; called by muse, mutect2, varscan2
- ZNF292 | c.5757A>G p.L1919= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs768040177, COSV60540560; called by muse, mutect2, varscan2
- ZNF600 | c.1686C>T p.T562= | Silent (SNP) | VAF 155/1274 reads (12%) | catalogued as COSV57742998; called by muse, mutect2, varscan2
- ZNF883 | c.87C>A p.T29= | Silent (SNP) | VAF 67/118 reads (57%) | catalogued as COSV71309118; called by muse, mutect2, varscan2
- ANK1 | c.5395-1245G>A | Intron (SNP) | VAF 31/71 reads (44%) | catalogued as COSV55884988; called by muse, mutect2, varscan2
- ANKRD13C | chr1:70355176 G>A | 5'Flank (SNP) | VAF 12/23 reads (52%) | catalogued as COSV52032252; called by muse, mutect2, varscan2
- LMO3 | c.*2C>G | 3'UTR (SNP) | VAF 79/218 reads (36%) | catalogued as COSV53783309; called by muse, mutect2, varscan2
